Surgical pathology report (de-identified scan), TCGA case TCGA-QH-A6XC, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Fondazione-Besta, specimen TCGA-QH-A6XC-01A (Primary Tumor).

OBJECT: PATHOLOGIST REPORT

Code:

Gender: M

Age:

Date of surgery:

Localization: R fronto-temporal

Diagnosis: Anaplastic astrocytoma (grade III WHO)

Name of Pathologist:

ICD O-3
Astrocytoma, grade III
9401/3
Site Brain, supratentorial NOS
C71.0
JW 8/12/13

Source: NCI Genomic Data Commons file 6c29c2b6-5862-4f5b-aab5-559c52f0cc36 (TCGA-QH-A6XC.27080340-615E-489D-932B-75AAD5C7D379.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).